Somatic mutation profile of tumor specimen 0DVZEM from CCDI case PBCNIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,368 days).
Specimen 0DVZEM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61f525c2-a3da-4540-ab42-6c7cafb61029.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZEF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71580a8c-9c5b-4726-9f0c-85cf47fe177c

The open-access MAF lists 27 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 6, Silent 4, 5'UTR 2, RNA 1, Nonsense Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPTL6 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1165277500; called by muse, mutect2
- CELSR2 | c.7756G>A p.D2586N | Missense Mutation (SNP) | VAF 108/257 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as rs757428274; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.312T>A p.D104E | Missense Mutation (SNP) | VAF 86/510 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61009869; called by muse, mutect2, varscan2
- MEPE | c.694A>C p.I232L | Missense Mutation (SNP) | VAF 62/423 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV63071769; called by muse, mutect2, varscan2
- NEUROD6 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 85/385 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771706009, COSV51770530; called by muse, mutect2, varscan2
- NR4A3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100432745; called by muse, mutect2
- SLC2A2 | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.246); catalogued as CD020088; called by muse, mutect2, varscan2
- UCP2 | c.337+1G>A p.X113_splice | Splice Site (SNP) | VAF 53/124 reads (43%) | catalogued as rs773260052, COSV60105096; called by muse, mutect2, varscan2
- ZNF763 | c.403G>A p.E135K (on ENST00000358987 / NM_001367172.2; = p.E138K on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs370834817, COSV59687772; called by muse, mutect2, varscan2
- ASH1L | c.8720C>A p.P2907H (on ENST00000368346 / NM_001366177.2; = p.P2902H on NM_018489.3) | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- BCL6 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- HSPG2 | c.6748G>T p.E2250* | Nonsense Mutation (SNP) | VAF 30/342 reads (9%) | called by muse, mutect2
- LAMA5 | c.6059G>A p.C2020Y | Missense Mutation (SNP) | VAF 184/368 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIT | c.1056C>T p.N352= | Silent (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.1002A>G p.R334= | Silent (SNP) | VAF 38/351 reads (11%) | called by muse, mutect2, varscan2
- RNF213 | c.12180C>T p.R4060= | Silent (SNP) | VAF 55/488 reads (11%) | called by muse, mutect2, varscan2
- ZNF304 | c.702C>T p.D234= | Silent (SNP) | VAF 18/260 reads (7%) | catalogued as rs1236244509; called by muse, mutect2
- ARMH4 | c.1831+15056del | Intron (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- BEGAIN | c.15-94C>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- CBR4 | c.535+22A>T | Intron (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- KLK4 | c.612+28C>T | Intron (SNP) | VAF 47/106 reads (44%) | catalogued as COSV100133746; called by muse, mutect2, varscan2
- MST1L | n.1421A>C | RNA (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- MXRA7 | c.*90A>G | 3'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- PLEC | c.524-730C>T | Intron (SNP) | VAF 9/276 reads (3%) | catalogued as rs1554726699; called by muse, mutect2
- RALGAPB | c.4143-74G>A | Intron (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- VPS50 | c.-92A>G | 5'UTR (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- ZNF689 | c.-67G>T | 5'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
